TARGET case TARGET-20-PATZVF — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/05f96fc1-93fd-4819-aed2-4f370c6a36e2

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 17 years; Vital status: Dead; Days to death: 14 days.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 17.7 years (6,469 days); Year of diagnosis: 2011; Days to last follow up: 14 days.
   Treatment given: Protocol identifier: AAML0631.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 14 days; Days to first event: 14 days; First event: Death without Remission; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 174 ×10³/µL; Blast Count 50%; Bone Marrow blast count 91%.

Biospecimens (1 sample)
- Sample TARGET-20-PATZVF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- Overall Survival Time in Days: 14
- WBC at Diagnosis: 173.8
- Bone marrow leukemic blast percentage (%): 91
- Peripheral blasts (%): 50
- Chloroma: No
- FAB Category: M3
- Cytogenetic Complexity: 1
- Primary Cytogenetic Code: PML-RARA
- ISCN: 46,XX,t(15;17)(q24;q21)[19]/46,idem,t(1;8)(p36.3;q22)[1]
- SCT in 1st CR: No
